Somatic mutation profile of tumor specimen C3N-03061-01 (aliquot CPT0208840014) from CPTAC case C3N-03061, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 62.9 years (22,974 days).
Specimen C3N-03061-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a753b23-6b75-41d3-b3c2-26965ec09b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03061-31 (Blood Derived Normal), aliquot CPT0208890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b6423af-a509-4b76-92da-59b4e4f07b7d

The open-access MAF lists 90 somatic variants for this specimen: 62 protein-altering or splice-affecting, 22 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 22, Intron 4, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1, 5'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 51/383 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13975G>A p.V4659M | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs369296047, COSV68951320; called by muse, mutect2, varscan2
- ADAM21 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs773176656, COSV104388377, COSV50804868; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4265C>T p.P1422L | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs199806479, COSV54470395; called by muse, mutect2, varscan2
- ATP7B | c.4094C>T p.S1365F | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747301758; called by muse, mutect2, varscan2
- C16orf54 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 124/762 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs775079638, COSV61477192; called by muse, mutect2, varscan2
- CCDC144A | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 55/412 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs745319880; called by muse, mutect2, varscan2
- CENPF | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); catalogued as rs936369720, COSV65273478, COSV65276969; called by muse, mutect2, varscan2
- CSMD1 | c.7663+1G>A p.X2555_splice (on ENST00000520002; = p.X2554_splice on NM_033225.6) | Splice Site (SNP) | VAF 12/89 reads (13%) | catalogued as rs747720579, COSV59289275; called by muse, varscan2
- GALNT17 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.034); catalogued as COSV61194968; called by muse, mutect2, varscan2
- GTPBP2 | c.1632+3G>A | Splice Region (SNP) | VAF 73/635 reads (11%) | catalogued as rs112143094; called by muse, mutect2, varscan2
- HAPLN4 | c.1118C>A p.A373E | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.245); catalogued as rs753334527; called by muse, mutect2, varscan2
- INPP5F | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs775019768, COSV62820038; called by muse, mutect2
- KIF7 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs794727744; called by muse, mutect2, varscan2
- KRTAP2-2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 52/480 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1303556673; called by muse, varscan2
- MMD2 | c.643G>A p.G215R (on ENST00000404774 / NM_001100600.2; = p.G191R on NM_198403.4) | Missense Mutation (SNP) | VAF 54/435 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs375097927; called by muse, varscan2
- OR2T3 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as rs780609392, COSV100613181, COSV62082590; called by muse, mutect2, varscan2
- OR4C6 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as rs372457190; called by muse, mutect2
- PAPOLB | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs1401691433, COSV68200319; called by muse, mutect2
- PCDHGA4 | c.1549C>T p.R517* | Nonsense Mutation (SNP) | VAF 41/236 reads (17%) | catalogued as rs1197287768, COSV53897391, COSV53982497; called by muse, mutect2, varscan2
- PDS5A | c.1328_1331del p.V443Afs*3 | Frame Shift Del (DEL) | VAF 30/215 reads (14%) | catalogued as rs1330544385; called by mutect2, pindel, varscan2
- PLEKHO2 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144415889; called by muse, mutect2, varscan2
- POM121L12 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 47/412 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as COSV68692958, COSV68693988; called by muse, mutect2, varscan2
- RADIL | c.3184G>A p.V1062M | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs747213896, COSV68201980; called by muse, mutect2, varscan2
- SCART1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.875); catalogued as rs1483431221; called by muse, mutect2
- SDE2 | c.10G>C p.A4P | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs897210734; called by muse, mutect2, varscan2
- SPHKAP | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1487948537, COSV60880827; called by muse, varscan2
- TAF1 | c.3455G>A p.R1152Q (on ENST00000373790 / NM_138923.4; = p.R1173Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/555 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52117001; called by muse, mutect2
- TCP11 | c.392G>A p.R131H (on ENST00000512012; = p.R69H on NM_018679.5) | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs150752841; called by muse, mutect2
- TMEM229B | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 59/361 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as rs926386994; called by muse, mutect2, varscan2
- TP53 | c.286dup p.S96Ffs*53 | Frame Shift Ins (INS) | VAF 34/202 reads (17%) | catalogued as COSV52948778; called by mutect2, pindel, varscan2
- TRIM47 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.159); catalogued as rs534004186; called by muse, mutect2, varscan2
- TRPS1 | c.2084G>A p.R695H (on ENST00000220888 / NM_001330599.2; = p.R708H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1322890657, COSV55234192; called by muse, mutect2, varscan2
- UNC80 | c.3212G>A p.R1071H | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs755460416, COSV55888864; called by muse, mutect2, varscan2
- VMAC | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs751669540, COSV100258937; called by muse, mutect2, varscan2
- ZNF676 | c.1280G>T p.C427F (on ENST00000650058; = p.C395F on NM_001001411.3) | Missense Mutation (SNP) | VAF 50/470 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68095163; called by muse, varscan2
- ANKFN1 | c.2773G>A p.E925K (on ENST00000653862; = p.E778K on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD30B | c.2569A>T p.N857Y | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ANKRD33B | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP7B | c.4395C>G p.I1465M | Missense Mutation (SNP) | VAF 81/706 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C19orf25 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.208); called by muse, varscan2
- CCBE1 | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CFH | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT2 | c.4085A>T p.D1362V | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA2026 | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2D | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- LAMA2 | c.7642A>G p.T2548A | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MARK1 | c.421G>C p.G141R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NLRP11 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- NPBWR2 | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPTX2 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 54/490 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRIP1 | c.3100T>A p.S1034T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- PCK1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PHTF1 | c.529A>T p.N177Y | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- QSER1 | c.722C>T p.S241F (on ENST00000399302; = p.S370F on NM_001076786.3) | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2
- SSC5D | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 77/586 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSC5D | c.3466G>A p.D1156N | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SSC5D | c.4137G>C p.Q1379H | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SSTR1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- VARS2 | c.695_697del p.Q232del | In Frame Del (DEL) | VAF 31/310 reads (10%) | called by pindel, varscan2
- VAT1L | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF790 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALG10B | c.228C>T p.V76= | Silent (SNP) | VAF 84/570 reads (15%) | called by muse, mutect2, varscan2
- ATP7B | c.3894C>G p.V1298= | Silent (SNP) | VAF 108/866 reads (12%) | catalogued as CD000921; called by muse, mutect2, varscan2
- ATP7B | c.3807C>A p.V1269= | Silent (SNP) | VAF 108/865 reads (12%) | called by muse, mutect2, varscan2
- CCNA1 | c.844C>T p.L282= | Silent (SNP) | VAF 55/347 reads (16%) | called by muse, mutect2, varscan2
- CELSR3 | c.1377C>T p.D459= | Silent (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
- CPXM1 | c.678C>T p.D226= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs375748016; called by muse, mutect2
- DCHS1 | c.6639C>G p.S2213= | Silent (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- FAM120A | c.1794C>A p.A598= | Silent (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- FIGNL2 | c.663G>A p.P221= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- GAS2L1 | c.1191G>A p.R397= | Silent (SNP) | VAF 30/204 reads (15%) | catalogued as rs1401020767; called by muse, mutect2, varscan2
- KCNA1 | c.1047G>A p.A349= | Silent (SNP) | VAF 34/335 reads (10%) | catalogued as rs748570236, COSV66836519; called by muse, mutect2, varscan2
- MARCO | c.1443C>T p.I481= | Silent (SNP) | VAF 30/270 reads (11%) | called by muse, mutect2, varscan2
- NT5C1A | c.1050T>C p.G350= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as COSV52496025; called by muse, mutect2, varscan2
- PEDS1 | c.438G>A p.P146= | Silent (SNP) | VAF 35/283 reads (12%) | catalogued as rs150986496; called by muse, mutect2, varscan2
- PPME1 | c.543T>C p.D181= | Silent (SNP) | VAF 45/337 reads (13%) | catalogued as COSV60297014; called by muse, mutect2, varscan2
- PRMT8 | c.666C>T p.Y222= | Silent (SNP) | VAF 59/582 reads (10%) | catalogued as rs763610227, COSV54214584, COSV99713579; called by muse, mutect2, varscan2
- RPTOR | c.3879C>T p.Y1293= | Silent (SNP) | VAF 48/413 reads (12%) | catalogued as rs781681867; called by muse, mutect2, varscan2
- SLC16A2 | c.75G>T p.P25= | Silent (SNP) | VAF 73/476 reads (15%) | called by muse, mutect2, varscan2
- SSC5D | c.4491G>A p.V1497= | Silent (SNP) | VAF 71/537 reads (13%) | catalogued as rs775432888; called by muse, mutect2, varscan2
- SSC5D | c.4599G>C p.R1533= | Silent (SNP) | VAF 72/534 reads (13%) | called by muse, mutect2, varscan2
- USPL1 | c.1569C>T p.L523= | Silent (SNP) | VAF 36/229 reads (16%) | called by muse, mutect2, varscan2
- ZNF423 | c.1848C>T p.S616= (on ENST00000563137 / NM_001379286.1; = p.S608= on NM_015069.4) | Silent (SNP) | VAF 30/265 reads (11%) | catalogued as rs376218086; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANAPC13 | c.*2G>A | 3'UTR (SNP) | VAF 14/92 reads (15%) | catalogued as rs151170068; called by muse, mutect2
- CLEC12A | c.10+23G>A | Intron (SNP) | VAF 24/217 reads (11%) | catalogued as rs551638853; called by muse, mutect2, varscan2
- ROBO2 | c.3761-2292G>A | Intron (SNP) | VAF 23/149 reads (15%) | catalogued as rs753114815; called by muse, mutect2, varscan2
- SUGP1 | c.539-144G>A | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- UBA1 | c.1-558G>A | Intron (SNP) | VAF 28/192 reads (15%) | catalogued as rs782182393; called by muse, mutect2, varscan2
- ZNF862 | chr7:149833838 G>A | 5'Flank (SNP) | VAF 52/354 reads (15%) | catalogued as rs751233432, COSV56223687, COSV56224866; called by muse, mutect2, varscan2
